Somatic mutation profile of tumor specimen TCGA-UY-A9PB-01A (aliquot TCGA-UY-A9PB-01A-11D-A38G-08) from TCGA case TCGA-UY-A9PB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 49.0 years (17,885 days).
Specimen TCGA-UY-A9PB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a283ab88-aaef-4595-999f-1884e30d22c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A9PB-10A (Blood Derived Normal), aliquot TCGA-UY-A9PB-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20d0162e-9049-44a3-bd27-ca5e17f3505b

The open-access MAF lists 642 somatic variants for this specimen: 450 protein-altering or splice-affecting, 174 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 392, Silent 174, Nonsense Mutation 29, Frame Shift Del 13, Splice Site 10, RNA 9, Intron 6, Frame Shift Ins 3, Splice Region 3, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780074, CM157012, COSV52668375, COSV52693504, COSV52778210; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.332T>G p.L111R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519997, CX942126, COSV52676090, COSV52699193, COSV52985195; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2402C>G p.S801C | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99220875; called by muse, mutect2
- AC005833.1 | c.1571G>A p.R524K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated, low confidence (0.17); catalogued as COSV99362525; called by muse, mutect2, varscan2
- ACAN | c.6409C>T p.H2137Y | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV100717196; called by muse, mutect2, varscan2
- ACBD3 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV100830899; called by muse, mutect2
- ACOT4 | c.1202A>G p.Q401R | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV100412790; called by muse, mutect2, varscan2
- ADAMTS14 | c.1341C>A p.S447R | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as rs1215781149, COSV100941400; called by muse, mutect2, varscan2
- ADAMTS5 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV53180165; called by muse, mutect2, varscan2
- ADAMTS9 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55781520, COSV99898817; called by muse, mutect2, varscan2
- ADSS1 | c.1313G>C p.G438A | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100272124; called by muse, mutect2
- AGPS | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as rs1407862856, COSV99931077; called by muse, mutect2, varscan2
- AHNAK | c.4433G>C p.G1478A | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV99945851; called by muse, mutect2, varscan2
- AKT3 | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55606144, COSV99794347, COSV99796240; called by muse, mutect2
- ANKRD12 | c.3167C>T p.S1056L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1475627148, COSV100040533; called by muse, mutect2, varscan2
- ANKRD50 | c.3619G>C p.D1207H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1560817047, COSV101538890; called by muse, mutect2
- ANOS1 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99390495; called by muse, mutect2
- AOC3 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV99519966; called by muse, mutect2, varscan2
- AQP6 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV100210090; called by muse, mutect2, varscan2
- AR | c.1770G>A p.G590= | Splice Region (SNP) | VAF 11/46 reads (24%) | catalogued as rs774286110, COSV65955145; called by muse, mutect2, varscan2
- ARHGEF18 | c.435G>C p.Q145H (on ENST00000359920 / NM_001130955.2; = p.Q41H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1359871355, COSV60473226; called by muse, mutect2, varscan2
- ASAP1 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs774096816, COSV63053663, COSV63053752; called by muse, mutect2, varscan2
- ATAD5 | c.4248A>C p.L1416F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100429694; called by muse, mutect2, varscan2
- ATG7 | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as COSV100606802; called by muse, mutect2, varscan2
- ATM | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99587638; called by muse, mutect2, varscan2
- ATP2B4 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100397144; called by muse, mutect2, varscan2
- ATP5F1A | c.1581G>A p.R527= | Splice Region (SNP) | VAF 13/64 reads (20%) | catalogued as COSV99958754; called by muse, mutect2, varscan2
- ATP6V0A2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100376847; called by muse, mutect2, varscan2
- ATP7B | c.4238C>A p.S1413Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV99666109; called by muse, mutect2, varscan2
- AXDND1 | c.864A>T p.R288S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100858258; called by muse, mutect2
- BRCA2 | c.3408A>G p.I1136M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV101203975; called by muse, mutect2, varscan2
- BRINP1 | c.2018T>G p.V673G | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV99774608; called by muse, mutect2, varscan2
- BTBD9 | c.1436A>G p.Y479C | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100021042; called by muse, mutect2, varscan2
- C17orf64 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs780153529, COSV99293353; called by muse, mutect2
- C22orf31 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99326270; called by muse, mutect2, varscan2
- C9orf131 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100397949, COSV56613995; called by muse, mutect2
- CASP1 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as COSV100782730; called by muse, mutect2, varscan2
- CCDC112 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV101100386; called by muse, mutect2
- CCDC117 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV99968811, COSV99968942; called by muse, mutect2, varscan2
- CCDC125 | c.1405G>C p.D469H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV101143509; called by muse, mutect2
- CCDC171 | c.1657C>G p.Q553E | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99899951; called by muse, mutect2, varscan2
- CCDC172 | c.481T>A p.L161I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV100319661; called by muse, mutect2
- CCDC185 | c.1738G>C p.D580H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs757503039, COSV100838755; called by mutect2, varscan2
- CCDC47 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 46/308 reads (15%) | catalogued as COSV99854002; called by muse, mutect2, varscan2
- CCNF | c.505C>A p.H169N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as COSV99563188; called by muse, mutect2, varscan2
- CD101 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.089); catalogued as COSV99869210; called by muse, mutect2, varscan2
- CD109 | c.2513C>T p.S838L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV99752754; called by muse, mutect2, varscan2
- CD1E | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV63771007; called by muse, mutect2, varscan2
- CD27 | c.446G>C p.S149T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99868987; called by muse, mutect2, varscan2
- CDH4 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.982); catalogued as rs903621472, COSV100848460; called by muse, mutect2, varscan2
- CDT1 | c.1210C>G p.P404A | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV99967078; called by muse, mutect2, varscan2
- CENPF | c.5021C>G p.S1674* | Nonsense Mutation (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100871527, COSV65273728; called by muse, mutect2
- CEP192 | c.4054G>A p.V1352I | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1449418623, COSV100380658; called by muse, mutect2
- CES2 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV100399084; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.041); catalogued as rs746682021, COSV99267234; called by muse, mutect2, varscan2
- CFAP61 | c.53G>C p.R18T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99843524, COSV99845777; called by muse, mutect2, varscan2
- CFHR3 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.932); catalogued as COSV100807430; called by muse, mutect2
- CFHR4 | c.1201G>C p.E401Q (on ENST00000367416 / NM_001201551.2; = p.E155Q on NM_006684.5) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.869); catalogued as COSV99259664; called by muse, mutect2, varscan2
- CHD1L | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100787347; called by muse, mutect2, varscan2
- CHSY3 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs148391625, COSV100518936; called by muse, mutect2, varscan2
- CHSY3 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.088); catalogued as COSV59277618; called by muse, mutect2, varscan2
- CKAP5 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100370467; called by muse, mutect2, varscan2
- CLCA4 | c.1468-1G>T p.X490_splice | Splice Site (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99760260; called by muse, mutect2, varscan2
- CLSTN2 | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.1); catalogued as COSV101515560; called by muse, mutect2, varscan2
- CMTR2 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV100579002; called by muse, mutect2, varscan2
- CNTNAP4 | c.2135G>T p.W712L | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV100269596; called by muse, mutect2, varscan2
- COL22A1 | c.3599C>A p.P1200H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100276608; called by muse, mutect2, varscan2
- COL3A1 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100482590; called by muse, mutect2, varscan2
- COL5A1 | c.4957G>A p.E1653K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs1286248077, COSV65676866; called by muse, mutect2, varscan2
- COLGALT2 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100730425; called by muse, mutect2, varscan2
- COPS8 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100585322; called by muse, mutect2, varscan2
- COX10 | c.1270C>G p.L424V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); catalogued as COSV99886054; called by muse, mutect2, varscan2
- CPB1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99294116; called by muse, mutect2, varscan2
- CRIP2 | c.543C>G p.I181M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.694); catalogued as COSV100231587; called by muse, mutect2, varscan2
- CRP | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1233787623, COSV99660370, COSV99660464; called by muse, mutect2, varscan2
- CSNK1D | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as rs1394868634, COSV53925419; called by muse, mutect2, varscan2
- CSPG4 | c.3830C>T p.S1277L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1308817846, COSV57903499; called by muse, mutect2, varscan2
- CTSV | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99414313; called by muse, mutect2, varscan2
- CTSZ | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.539); catalogued as COSV99413443; called by muse, mutect2, varscan2
- CUBN | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100912139; called by muse, mutect2, varscan2
- DCAF12 | c.441G>C p.E147D | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as COSV100778344; called by muse, mutect2, varscan2
- DCAF8L1 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV101491401; called by muse, mutect2, varscan2
- DCST2 | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.238); catalogued as COSV99420837; called by muse, mutect2, varscan2
- DDR1 | c.1852G>A p.E618K (on ENST00000324771; = p.E581K on NM_001954.4) | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764269995, COSV100241085, COSV61325131; called by muse, mutect2, varscan2
- DDX18 | c.152G>C p.R51T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.014); catalogued as COSV99604366; called by muse, mutect2, varscan2
- DELE1 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV99519654; called by muse, mutect2, varscan2
- DHCR7 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100831741, COSV100831947; called by muse, mutect2, varscan2
- DHRSX | c.310del p.A104Lfs*3 | Frame Shift Del (DEL) | VAF 39/187 reads (21%) | catalogued as COSV58138331; called by mutect2, pindel, varscan2
- DISC1 | c.2255G>T p.W752L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV100790220; called by muse, mutect2, varscan2
- DLG5 | c.4474G>A p.D1492N | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as COSV100967283; called by muse, mutect2, varscan2
- DMWD | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.018); catalogued as COSV99536970; called by muse, mutect2
- DNAH11 | c.10666G>T p.G3556C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100177540; called by muse, mutect2, varscan2
- DNAJC13 | c.2743C>G p.L915V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs1435282575, COSV99606708; called by muse, mutect2
- DNAJC18 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100122068; called by muse, mutect2, varscan2
- DNPH1 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112399499, COSV99334862; called by muse, mutect2, varscan2
- DTX2 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184401; called by muse, mutect2, varscan2
- DYSF | c.2606A>G p.Q869R | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.146); catalogued as rs762697705, COSV99244748; called by muse, mutect2
- ECE1 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs779020235, COSV99941436; called by mutect2, varscan2
- EFCAB13 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as COSV58952055; called by muse, mutect2, varscan2
- EGFLAM | c.2893T>C p.Y965H (on ENST00000354891 / NM_001205301.2; = p.Y957H on NM_152403.4) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379901; called by muse, mutect2, varscan2
- EIF3M | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); catalogued as COSV100024872; called by muse, mutect2, varscan2
- ELANE | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as rs1408272130, COSV99708673; called by muse, mutect2, varscan2
- ELOA2 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1363716505, COSV99796040; called by muse, mutect2, varscan2
- EMC1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV61887116; called by muse, mutect2
- EP300 | c.4200T>G p.S1400R | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99607524; called by muse, mutect2, varscan2
- EPHA3 | c.2710G>T p.D904Y | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60699564, COSV60725267; called by muse, mutect2, varscan2
- EPHX4 | c.547C>G p.P183A | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100952647; called by muse, mutect2
- EPS8L2 | c.1450C>G p.H484D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV100585343, COSV59349882; called by muse, mutect2, varscan2
- ESM1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV67318624; called by muse, mutect2, varscan2
- ESYT2 | c.846C>G p.I282M (on ENST00000613624; = p.I206M on NM_020728.3) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV99276209; called by muse, mutect2, varscan2
- ETS2 | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV100711193; called by muse, mutect2, varscan2
- ETV6 | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56765865, COSV56766513; called by muse, mutect2, varscan2
- EXOSC10 | c.2571A>T p.K857N (on ENST00000376936 / NM_001001998.3; = p.K832N on NM_002685.4) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100442185; called by muse, mutect2, varscan2
- F13A1 | c.1513A>G p.K505E | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV99342321; called by muse, mutect2, varscan2
- FAM209B | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.959); catalogued as COSV100990923; called by muse, mutect2, varscan2
- FAM83E | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs552900271, COSV99320117; called by muse, mutect2, varscan2
- FAM83G | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100524849; called by muse, mutect2, varscan2
- FAT4 | c.12027T>A p.S4009R | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); catalogued as COSV100627363; called by muse, mutect2, varscan2
- FAXC | c.196A>T p.T66S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101067055; called by muse, mutect2, varscan2
- FETUB | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV54005383, COSV54006487; called by muse, mutect2, varscan2
- FLG | c.3571T>A p.S1191T | Missense Mutation (SNP) | VAF 53/487 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV100910636; called by muse, mutect2, varscan2
- FMN2 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs775540805, COSV60414993, COSV60461217; called by muse, mutect2, varscan2
- FMN2 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV60451271; called by muse, mutect2
- FOXD4L5 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV101073044; called by muse, mutect2
- FOXM1 | c.690G>C p.Q230H | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.711); catalogued as COSV100700801; called by muse, mutect2
- FOXN2 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100489011; called by muse, mutect2, varscan2
- GABRA5 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566890866, COSV100164794; called by muse, mutect2, varscan2
- GAL3ST4 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100385363, COSV57586172; called by muse, mutect2, varscan2
- GALNT1 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99321889; called by muse, varscan2
- GAPT | c.377G>C p.G126A | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV100576244; called by muse, mutect2
- GBF1 | c.1369G>A p.E457K (on ENST00000369983 / NM_001377137.1; = p.E456K on NM_004193.3) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100890342; called by muse, mutect2
- GCFC2 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | catalogued as rs1366212419, COSV100319407, COSV58080035; called by muse, mutect2, varscan2
- GOLGA3 | c.2331C>G p.I777M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99202296; called by muse, mutect2, varscan2
- GPNMB | c.1129T>C p.F377L (on ENST00000381990 / NM_001005340.2; = p.F365L on NM_002510.3) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99326296; called by muse, mutect2
- GPR6 | c.290T>C p.I97T | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99254110; called by muse, mutect2, varscan2
- GRIN2C | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV99500623; called by muse, mutect2
- GYPB | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.849); catalogued as rs1461379536, COSV99301109; called by muse, mutect2, varscan2
- H2AC6 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100019764; called by muse, mutect2, varscan2
- H2BC15 | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.304); catalogued as COSV100356912, COSV57586617; called by muse, mutect2, varscan2
- H2BC15 | c.377+3G>A | Splice Region (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100356914; called by muse, mutect2
- H2BC9 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 14/202 reads (7%) | catalogued as COSV55100448, COSV99769028; called by muse, mutect2
- HBE1 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs200008612, COSV99496039; called by muse, mutect2, varscan2
- HCLS1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100100383; called by muse, mutect2, varscan2
- HCN1 | c.2608G>C p.E870Q | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.058); catalogued as COSV100298842; called by muse, mutect2, varscan2
- HECTD3 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs199544969, COSV55799962; called by muse, mutect2, varscan2
- HECW1 | c.1696C>G p.L566V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101222892, COSV101222895; called by muse, mutect2, varscan2
- HERC2 | c.10667C>T p.S3556L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99869926; called by muse, mutect2, varscan2
- HNRNPCL1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV100508815; called by muse, mutect2, varscan2
- HOMER1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV56526569; called by muse, mutect2, varscan2
- HOXA10 | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99385287; called by muse, mutect2, varscan2
- HOXB3 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV100290567; called by muse, mutect2, varscan2
- HOXC8 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99236665; called by muse, mutect2, varscan2
- HUWE1 | c.3445C>T p.P1149S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99470823; called by muse, mutect2, varscan2
- HYAL4 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as COSV99772084; called by muse, mutect2, varscan2
- ICE2 | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV99831318; called by muse, mutect2, varscan2
- IDS | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as CM128171, COSV100557854, COSV61715409; called by muse, mutect2, varscan2
- IFI16 | c.1168A>C p.K390Q | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV55533843, COSV99857104; called by muse, mutect2
- IGHV3-72 | c.157A>G p.M53V | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.209); catalogued as rs775669168, COSV101455361; called by muse, mutect2, varscan2
- IGSF22 | c.1086C>G p.F362L | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV100079239; called by muse, mutect2, varscan2
- IPO4 | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99937793; called by muse, mutect2
- IPO5 | c.1492C>T p.Q498* | Nonsense Mutation (SNP) | VAF 24/130 reads (18%) | catalogued as COSV99847034; called by muse, mutect2, varscan2
- IRF2 | c.925C>G p.Q309E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV101165775; called by muse, mutect2, varscan2
- ITGA6 | c.2761G>A p.E921K (on ENST00000442250; = p.E882K on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV99905137; called by muse, mutect2, varscan2
- KALRN | c.7553C>T p.S2518L (on ENST00000360013 / NM_001024660.4; = p.S821L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as rs1158538180, COSV99361186; called by muse, mutect2, varscan2
- KATNIP | c.1732A>G p.T578A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV99850023; called by muse, mutect2, varscan2
- KAZN | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.678); catalogued as rs773002622, COSV63207903; called by muse, mutect2, varscan2
- KCNA5 | c.1540G>A p.V514I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1172712297, COSV52904278, COSV52905346, COSV52907390; called by muse, mutect2, varscan2
- KCNQ3 | c.2374C>A p.L792M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as COSV101195744; called by muse, mutect2
- KCNT1 | c.3073G>A p.E1025K (on ENST00000488444; = p.E1044K on NM_020822.3) | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV99705091; called by muse, varscan2
- KDM4C | c.3159G>C p.Q1053H | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.021); catalogued as COSV101184671; called by muse, mutect2, varscan2
- KDM5A | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV101238629; called by muse, mutect2, varscan2
- KDM7A | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99134003; called by muse, mutect2
- KIAA1522 | c.1498G>T p.V500L (on ENST00000373480 / NM_001198972.2; = p.V559L on NM_020888.3) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs983608315, COSV99614191; called by muse, mutect2
- KIAA1614 | c.623T>A p.L208* | Nonsense Mutation (SNP) | VAF 16/130 reads (12%) | catalogued as COSV100851270; called by muse, mutect2, varscan2
- KIAA1614 | c.624G>T p.L208F | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV100851271; called by muse, mutect2, varscan2
- KIAA1958 | c.1458C>G p.D486E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100515887, COSV61724828; called by muse, mutect2, varscan2
- KIAA2013 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV100927113; called by mutect2, varscan2
- KIF3A | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV101109254, COSV101109502; called by muse, mutect2, varscan2
- KIN | c.371G>C p.R124T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101092434; called by muse, mutect2, varscan2
- KLHL40 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99825357; called by muse, mutect2, varscan2
- KLK13 | c.509-1G>T p.X170_splice | Splice Site (SNP) | VAF 31/148 reads (21%) | catalogued as COSV99335188; called by muse, mutect2, varscan2
- KNDC1 | c.1797A>T p.R599S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.114); catalogued as COSV100463514; called by muse, mutect2
- KRTAP5-1 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV101192861, COSV101192869; called by muse, varscan2
- L3MBTL1 | c.1130C>G p.S377C (on ENST00000418998 / NM_001377303.1; = p.S287C on NM_015478.7) | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100916917; called by muse, mutect2, varscan2
- L3MBTL3 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs758651675, COSV100695756; called by muse, mutect2, varscan2
- LILRB5 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100300123; called by muse, mutect2, varscan2
- LIPE | c.2637G>C p.L879F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs770248142, COSV54921526, COSV99733862; called by muse, mutect2, varscan2
- LRFN3 | c.816C>A p.C272* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99873191; called by muse, mutect2
- LRP2 | c.8288A>G p.Y2763C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV99786767; called by muse, mutect2, varscan2
- LRRC4B | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100975848; called by muse, mutect2
- LYPD4 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100419320; called by muse, mutect2, varscan2
- LYPLA2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as COSV65720611, COSV65720966; called by muse, mutect2, varscan2
- MATN1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs1329564412, COSV101056187; called by muse, mutect2
- MC5R | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777929535, COSV100228939; called by muse, mutect2, varscan2
- MCF2L2 | c.487-1G>A p.X163_splice | Splice Site (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100191469, COSV61058938; called by muse, mutect2, varscan2
- MCHR2 | c.90T>A p.S30R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99911563; called by muse, mutect2, varscan2
- MDN1 | c.12839A>G p.Q4280R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1437883496, COSV101020825; called by muse, mutect2, varscan2
- MED8 | c.660A>C p.L220F | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.692); catalogued as COSV99318320; called by muse, mutect2, varscan2
- MEGF6 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs764576361, COSV53895186; called by muse, mutect2, varscan2
- MIA2 | c.2147G>C p.G716A | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV54498399; called by muse, mutect2, varscan2
- MICAL3 | c.1374G>C p.K458N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99260126; called by muse, mutect2, varscan2
- MICALL1 | c.2144-1G>C p.X715_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99317043; called by muse, mutect2, varscan2
- MID1 | c.434G>T p.C145F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071002, COSV58191660; called by muse, mutect2, varscan2
- MIGA2 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV99477415; called by muse, mutect2, varscan2
- MKI67 | c.4094C>T p.A1365V | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV64073306; called by muse, mutect2, varscan2
- MPG | c.605A>G p.K202R | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.612); catalogued as COSV99549824; called by muse, mutect2
- MROH2B | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV68190449; called by muse, mutect2, varscan2
- MROH2B | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs375560826; called by muse, mutect2, varscan2
- MSH5 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as rs777865774, COSV100994715; called by muse, mutect2, varscan2
- MST1R | c.3811-1G>A p.X1271_splice | Splice Site (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99617876; called by muse, mutect2
- MTRF1L | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100921913; called by muse, mutect2, varscan2
- MUC21 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1163221829, COSV100888836; called by muse, mutect2, varscan2
- MUC5AC | c.15190G>A p.G5064S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439184088, COSV100611326; called by muse, mutect2, varscan2
- MXRA5 | c.2767A>G p.T923A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99475965; called by muse, mutect2, varscan2
- MYBPC2 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as rs367620888; called by muse, mutect2
- MYH10 | c.4171G>T p.E1391* | Nonsense Mutation (SNP) | VAF 18/141 reads (13%) | catalogued as COSV99344257; called by muse, mutect2, varscan2
- MYO15A | c.8995G>A p.D2999N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV99231370; called by muse, mutect2, varscan2
- MYO9B | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1438756303, COSV101261340; called by muse, mutect2
- NAPSA | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99515731; called by muse, mutect2, varscan2
- NAT10 | c.2673G>C p.L891F | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV99139940; called by muse, mutect2, varscan2
- NAT16 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as rs1173332299, COSV100296205; called by muse, mutect2, varscan2
- NBAS | c.5461C>T p.Q1821* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as rs1241325718, COSV99867599; called by muse, mutect2, varscan2
- NCKAP5 | c.5065G>A p.E1689K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV100490302; called by mutect2, varscan2
- NCKAP5 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100490304; called by muse, mutect2, varscan2
- NEU2 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs376559802; called by muse, mutect2, varscan2
- NFYB | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV99527107; called by muse, mutect2
- NHLRC2 | c.2161G>C p.E721Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV100992896; called by muse, mutect2, varscan2
- NKAP | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.298); catalogued as COSV100538236, COSV57630788; called by muse, mutect2, varscan2
- NLRP8 | c.2964G>C p.L988F | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99404798; called by muse, mutect2, varscan2
- NLRP9 | c.2145G>C p.K715N | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV60467098; called by muse, mutect2, varscan2
- NPHP3 | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs749743350, COSV100446635; called by muse, mutect2, varscan2
- NRAP | c.4156C>T p.H1386Y (on ENST00000359988 / NM_001322945.2; = p.H1351Y on NM_006175.4) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100748297, COSV63488177; called by muse, mutect2, varscan2
- NRAP | c.3298G>A p.D1100N (on ENST00000359988 / NM_001322945.2; = p.D1065N on NM_006175.4) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV63494907; called by muse, mutect2, varscan2
- NRBF2 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.976); catalogued as COSV99515029; called by muse, mutect2, varscan2
- NRF1 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV99781567; called by muse, mutect2
- NRG1 | c.122G>A p.W41* (on ENST00000523534; = p.W188* on NM_013962.2) | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs1273105046, COSV101584761; called by muse, mutect2, varscan2
- OLIG3 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV100880225; called by muse, mutect2, varscan2
- OR13C9 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1277048381, COSV52244119; called by muse, mutect2, varscan2
- OR13H1 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100088135, COSV58547983; called by muse, mutect2, varscan2
- OR1A1 | c.826T>C p.Y276H | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100410723; called by muse, mutect2, varscan2
- OR1L8 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1392148759, COSV100508427, COSV59185990; called by muse, mutect2, varscan2
- OR2D2 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV55058198; called by muse, mutect2, varscan2
- OR2M3 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV101513399; called by muse, mutect2, varscan2
- OR4K5 | c.495C>A p.N165K | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV100262168; called by muse, mutect2
- OR4K5 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60003946, COSV60004755; called by muse, mutect2
- OR51A7 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100834601; called by muse, mutect2, varscan2
- OR52B6 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV61447924; called by muse, mutect2, varscan2
- OR5T3 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.052); catalogued as rs761277163, COSV100282691, COSV57379846; called by muse, mutect2
- OR8G5 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100422263, COSV100422627, COSV100422691; called by muse, mutect2, varscan2
- OR8I2 | c.796T>C p.S266P | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100135872; called by muse, mutect2, varscan2
- ORC2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV99309413; called by muse, mutect2, varscan2
- OSBP2 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100212696; called by muse, mutect2, varscan2
- OSBPL10 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.607); catalogued as COSV101159016; called by muse, mutect2, varscan2
- OSBPL11 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | catalogued as COSV99953991; called by muse, varscan2
- OSTN | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429709555, COSV100174154, COSV59138875; called by muse, mutect2
- PABPC1 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100589337; called by muse, mutect2, varscan2
- PAH | c.646T>A p.Y216N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV100187682; called by muse, mutect2, varscan2
- PAIP2B | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99731485; called by muse, mutect2, varscan2
- PAX5 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100814076; called by muse, mutect2, varscan2
- PCDHGC3 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.028); catalogued as COSV99338375; called by muse, mutect2, varscan2
- PCNT | c.6526G>C p.D2176H | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs746930023, COSV100855088; called by muse, mutect2, varscan2
- PDE10A | c.1986-1G>A p.X662_splice | Splice Site (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100604579; called by muse, mutect2, varscan2
- PDSS1 | c.344T>A p.L115H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100873545; called by muse, mutect2, varscan2
- PEG3 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs1406007824, COSV55646277; called by muse, mutect2, varscan2
- PEX7 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100576439; called by muse, mutect2, varscan2
- PHF3 | c.3029T>C p.L1010P | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012938; called by muse, mutect2, varscan2
- PI4KB | c.407C>G p.S136* (on ENST00000368873 / NM_001369623.1; = p.S148* on NM_002651.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/135 reads (10%) | catalogued as COSV99649343; called by muse, mutect2
- PIEZO2 | c.6994C>G p.L2332V | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99554530; called by muse, mutect2, varscan2
- PIGL | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs747774912, COSV99247865; called by muse, mutect2, varscan2
- PIK3R4 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100768266; called by muse, mutect2, varscan2
- PIP5K1B | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55253123, COSV99598088; called by muse, mutect2, varscan2
- PLA2R1 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99322286; called by muse, mutect2, varscan2
- PLAAT5 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); catalogued as COSV100080355; called by muse, mutect2, varscan2
- PLCH1 | c.1351G>A p.G451R (on ENST00000340059 / NM_001130960.2; = p.G463R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58189132; called by muse, mutect2, varscan2
- PLG | c.2224A>G p.T742A | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.165); catalogued as COSV100368887; called by muse, mutect2
- PLS3 | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99171609; called by muse, mutect2, varscan2
- PLXNB2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.5); catalogued as COSV100833871; called by muse, mutect2, varscan2
- POLQ | c.86C>A p.A29D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV51752462, COSV99951709; called by muse, mutect2, varscan2
- PPEF1 | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 48/145 reads (33%) | catalogued as COSV100583585; called by muse, mutect2, varscan2
- PPP1CC | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.071); catalogued as COSV100534785; called by muse, mutect2, varscan2
- PPP1R8 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as COSV99360845; called by muse, mutect2
- PPP2R3B | c.880-1G>C p.X294_splice | Splice Site (SNP) | VAF 9/99 reads (9%) | catalogued as COSV101065504, COSV66814340; called by muse, mutect2
- PPTC7 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV100845681; called by muse, mutect2
- PRAMEF2 | c.932A>T p.K311M | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.893); catalogued as COSV99534870; called by muse, mutect2, varscan2
- PRDM10 | c.2418G>C p.K806N | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100456600, COSV100456804; called by muse, mutect2, varscan2
- PRDM14 | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV99399910; called by muse, mutect2
- PREX1 | c.1589A>T p.K530I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV100906089; called by muse, mutect2, varscan2
- PRF1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs201468340, CM071927, CX151487, COSV64615741; called by muse, mutect2, varscan2
- PTPN13 | c.6014C>A p.S2005* (on ENST00000411767 / NM_080683.3; = p.S1986* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100364148; called by muse, mutect2, varscan2
- PTPRT | c.3287C>G p.A1096G | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV100625555; called by muse, mutect2, varscan2
- PTPRZ1 | c.3635C>T p.P1212L | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as COSV101099658, COSV66429584; called by muse, mutect2
- PXDNL | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1293373999, COSV100681736; called by muse, mutect2, varscan2
- QRICH2 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.556); catalogued as rs1466031833; called by muse, mutect2, varscan2
- RAB18 | c.518C>G p.P173R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100803783; called by muse, mutect2, varscan2
- RECK | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs139919356, COSV65035512; called by muse, mutect2, varscan2
- RETREG2 | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); catalogued as COSV56087241; called by muse, mutect2, varscan2
- RGL2 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV101442484; called by muse, mutect2
- RIN3 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.527); catalogued as rs1323025947, COSV99378591; called by muse, mutect2, varscan2
- RIN3 | c.2036T>C p.V679A | Missense Mutation (SNP) | VAF 75/448 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.113); catalogued as COSV99378593; called by muse, mutect2, varscan2
- RNF213 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs756336687, COSV100173132; called by muse, mutect2, varscan2
- RRBP1 | c.3565G>A p.E1189K (on ENST00000377813 / NM_001365613.2; = p.E756K on NM_004587.3) | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.12); catalogued as rs1291420253, COSV99853639; called by muse, mutect2, varscan2
- RSPH10B2 | c.1602G>C p.Q534H | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99785963; called by muse, mutect2, varscan2
- RYR1 | c.9724G>T p.D3242Y | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.936); catalogued as COSV62094217; called by muse, mutect2
- RYR1 | c.11033C>T p.S3678L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100614719; called by muse, mutect2
- RYR2 | c.14016G>A p.M4672I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100768330, COSV63721946; called by muse, mutect2
- RYR3 | c.99G>C p.Q33H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV101212075; called by muse, mutect2, varscan2
- SAP30 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV99633010; called by muse, mutect2
- SAT2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV99352116; called by muse, mutect2, varscan2
- SCN3A | c.2338G>T p.E780* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as rs1553526499, COSV99325913; called by muse, mutect2, varscan2
- SCN7A | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs1412559467, COSV101313099; called by muse, mutect2
- SERPINA10 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100003646; called by muse, mutect2
- SERPINA5 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs567913291, COSV61575153; called by muse, mutect2, varscan2
- SF3B3 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV100209609; called by muse, mutect2, varscan2
- SHANK2 | c.1936+1G>A p.X646_splice | Splice Site (SNP) | VAF 7/154 reads (5%) | catalogued as COSV99572491; called by muse, mutect2
- SIGLECL1 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV100323833; called by muse, mutect2, varscan2
- SIN3A | c.998A>G p.H333R | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845055; called by muse, mutect2, varscan2
- SIRPB1 | c.1026A>T p.K342N | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as COSV99498177; called by muse, mutect2
- SIRPG | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.205); catalogued as COSV99403489; called by muse, mutect2, varscan2
- SIRT3 | c.650A>G p.H217R | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs772528818, COSV100728741; called by muse, mutect2, varscan2
- SLC23A3 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55408705, COSV99840894; called by muse, mutect2
- SLC24A1 | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99978074; called by muse, mutect2, varscan2
- SLC25A23 | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51191943, COSV99901952; called by muse, mutect2, varscan2
- SLC32A1 | c.1220A>G p.K407R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV54148716; called by muse, mutect2, varscan2
- SLC44A2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV100213044, COSV100213598; called by muse, mutect2, varscan2
- SLC6A1 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99822460; called by muse, mutect2
- SLC6A14 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100902517; called by muse, mutect2, varscan2
- SLC6A19 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs766877452, COSV100443266; called by mutect2, varscan2
- SLCO1B3 | c.1255T>C p.F419L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs1418913402, COSV53941078; called by muse, mutect2, varscan2
- SLFN13 | c.328A>G p.K110E | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV53196291; called by muse, mutect2, varscan2
- SLITRK3 | c.2524G>T p.A842S | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as COSV99578604; called by muse, mutect2, varscan2
- SLITRK3 | c.2201del p.P734Lfs*59 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | catalogued as COSV53849006; called by mutect2, pindel, varscan2
- SMPDL3B | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as rs759636888, COSV65870697; called by muse, mutect2, varscan2
- SNAP91 | c.1262C>G p.S421* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99534547; called by muse, mutect2, varscan2
- SNX20 | c.554C>A p.T185K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100319124; called by muse, mutect2
- SPAG1 | c.1697G>C p.R566T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV99308445; called by muse, mutect2
- SPATA31D1 | c.1051del p.A352Hfs*39 | Frame Shift Del (DEL) | VAF 13/124 reads (10%) | catalogued as COSV61193594; called by mutect2, pindel, varscan2
- SPECC1 | c.2991C>G p.F997L | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as rs780424477, COSV54966693, COSV99821349; called by muse, mutect2, varscan2
- SPHKAP | c.1553G>C p.R518T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100763754; called by muse, mutect2, varscan2
- SPRING1 | c.128G>C p.R43T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV99732224; called by muse, mutect2, varscan2
- SPTA1 | c.555G>C p.E185D | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.313); catalogued as COSV100934421; called by muse, mutect2
- SRCAP | c.6328C>T p.R2110C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371360318; called by muse, mutect2, varscan2
- SRP54 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV99392428; called by muse, mutect2, varscan2
- SYCP2 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370668219, COSV62770736; called by muse, mutect2
- SYCP2 | c.1841A>G p.K614R | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100698006; called by muse, mutect2
- SYNE1 | c.22048G>A p.G7350R (on ENST00000367255 / NM_182961.4; = p.G7279R on NM_033071.3) | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs751849747, COSV99037850; called by muse, mutect2, varscan2
- TACR3 | c.472T>C p.C158R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100510136; called by muse, mutect2, varscan2
- TAF2 | c.2948G>C p.R983T | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs778496041, COSV100978462; called by muse, mutect2, varscan2
- TAS2R9 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as rs754460148, COSV99553602; called by muse, mutect2, varscan2
- TBC1D22B | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs1450523284, COSV100996692; called by muse, mutect2, varscan2
- TBCE | c.1133T>A p.L378Q (on ENST00000366601; = p.L441Q on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100782978; called by muse, mutect2, varscan2
- TBX18 | c.1332G>T p.Q444H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.73); catalogued as COSV100858443, COSV100858590; called by muse, mutect2, varscan2
- TEX15 | c.5473C>A p.L1825M (on ENST00000256246; = p.L2208M on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99820795; called by muse, mutect2, varscan2
- THADA | c.4253C>T p.S1418L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100368041; called by muse, varscan2
- THSD7B | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs568467115, COSV55677825; called by mutect2, varscan2
- TIAM2 | c.4954G>A p.E1652K (on ENST00000529824; = p.E1623K on NM_012454.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.079); catalogued as COSV99265114; called by muse, mutect2
- TM7SF3 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100544660; called by muse, mutect2, varscan2
- TMCC1 | c.1118C>T p.A373V (on ENST00000393238 / NM_001349268.2; = p.A49V on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100260766; called by muse, mutect2, varscan2
- TMEM143 | c.261A>G p.I87M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.38); catalogued as rs1354526163, COSV99506962; called by muse, mutect2, varscan2
- TMEM200C | c.1846C>G p.L616V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs746264079, COSV101274793; called by muse, mutect2, varscan2
- TNFAIP6 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV99693708; called by muse, mutect2, varscan2
- TNN | c.3760-1G>A p.X1254_splice | Splice Site (SNP) | VAF 9/85 reads (11%) | catalogued as rs774269379, COSV99511216; called by mutect2, varscan2
- TOP2A | c.130T>G p.L44V | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV101396077; called by muse, mutect2, varscan2
- TPO | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100219878; called by muse, mutect2, varscan2
- TPX2 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100301551; called by muse, mutect2
- TRAV8-3 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as rs1433348472; called by muse, mutect2, varscan2
- TRERF1 | c.2666A>G p.K889R | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs1323184179, COSV100550064; called by muse, mutect2, varscan2
- TRIM42 | c.13A>T p.M5L | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs746805238, COSV99648031; called by muse, mutect2, varscan2
- TRPC1 | c.2002T>G p.W668G (on ENST00000476941 / NM_001251845.2; = p.W634G on NM_003304.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99858296; called by muse, mutect2, varscan2
- TSEN2 | c.1221G>C p.L407F | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99538853; called by muse, mutect2, varscan2
- TSGA13 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV100449582; called by muse, mutect2
- TSN | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101067449, COSV67605412; called by muse, mutect2, varscan2
- TTC16 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58853198; called by muse, mutect2, varscan2
- TTC17 | c.29G>C p.R10P | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV50015651, COSV99234769, COSV99236171; called by muse, mutect2
- TTN | c.57392A>T p.D19131V (on ENST00000591111; = p.D11707V on NM_003319.4) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | PolyPhen possibly damaging (0.787); catalogued as COSV100596872; called by muse, mutect2, varscan2
- TTN | c.14992G>A p.V4998I (on ENST00000591111; = p.V4071I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | PolyPhen benign (0.003); catalogued as COSV100596880; called by muse, mutect2, varscan2
- TTN | c.3853G>C p.E1285Q (on ENST00000591111; = p.E1239Q on NM_003319.4) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | PolyPhen probably damaging (0.964); catalogued as COSV100596885; called by muse, mutect2, varscan2
- TUBD1 | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100359985; called by muse, mutect2, varscan2
- TULP4 | c.978C>A p.F326L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV100893188; called by muse, mutect2, varscan2
- TYMS | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as rs765591852, COSV51896855; called by muse, mutect2, varscan2
- UBN2 | c.3860C>T p.S1287L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV99943672; called by muse, mutect2
- UBQLN3 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV61165527; called by muse, mutect2, varscan2
- UQCRFS1 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100508030; called by muse, mutect2, varscan2
- USP29 | c.1823G>C p.R608T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as COSV99517741; called by muse, varscan2
- USP29 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.543); catalogued as rs776080625, COSV54140190, COSV54144382; called by muse, varscan2
- USP53 | c.832A>G p.R278G | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs747146943, COSV99917535; called by muse, mutect2, varscan2
- USP9X | c.7111G>C p.D2371H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1468788790, COSV61075960; called by muse, varscan2
- UTP20 | c.7804G>A p.D2602N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99880887; called by muse, mutect2, varscan2
- UTRN | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV100839638; called by muse, mutect2, varscan2
- VEPH1 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV100747401; called by muse, mutect2, varscan2
- VIRMA | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99887742; called by muse, mutect2, varscan2
- WASHC2C | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100313801; called by muse, mutect2, varscan2
- WASHC5 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780719370, COSV100572579; called by muse, mutect2, varscan2
- XRCC2 | c.566T>A p.L189Q | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100831579; called by muse, mutect2, varscan2
- YEATS2 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV100527523; called by muse, mutect2, varscan2
- YME1L1 | c.1906G>A p.E636K (on ENST00000326799 / NM_139312.3; = p.E579K on NM_014263.4) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1388915740, COSV100463319; called by muse, mutect2, varscan2
- YTHDC1 | c.1703G>A p.R568Q (on ENST00000344157 / NM_001031732.4; = p.R550Q on NM_133370.4) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV60011489; called by muse, mutect2, varscan2
- YTHDC1 | c.811A>G p.S271G | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs768442650, COSV100704611; called by muse, mutect2, varscan2
- YTHDF1 | c.1569C>G p.I523M | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.656); catalogued as COSV100945546, COSV64832622; called by muse, mutect2, varscan2
- ZBTB22 | c.651C>G p.F217L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.281); catalogued as COSV99801546; called by muse, mutect2, varscan2
- ZC3H12A | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.076); catalogued as COSV100897649, COSV66104153; called by muse, mutect2, varscan2
- ZC3H18 | c.701G>A p.W234* | Nonsense Mutation (SNP) | VAF 24/121 reads (20%) | catalogued as COSV99963882, COSV99964519; called by muse, mutect2, varscan2
- ZFC3H1 | c.968G>C p.G323A | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as COSV101110352; called by muse, mutect2, varscan2
- ZFP28 | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV100019300, COSV56736100; called by muse, mutect2, varscan2
- ZMYM3 | c.3262G>A p.D1088N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100077502; called by muse, mutect2, varscan2
- ZMYM3 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.69); catalogued as COSV58738347; called by muse, mutect2, varscan2
- ZNF101 | c.942A>C p.K314N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV100543477; called by muse, mutect2, varscan2
- ZNF112 | c.2635C>T p.H879Y (on ENST00000337401 / NM_001083335.2; = p.H873Y on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100495511; called by muse, mutect2, varscan2
- ZNF213 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV101205937; called by muse, mutect2, varscan2
- ZNF215 | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV99549244; called by muse, mutect2, varscan2
- ZNF3 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99447117; called by muse, mutect2, varscan2
- ZNF341 | c.1726C>T p.P576S (on ENST00000375200 / NM_001282935.1; = p.P569S on NM_032819.4) | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100677753; called by muse, mutect2, varscan2
- ZNF354A | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as COSV100234338, COSV59983641; called by muse, mutect2, varscan2
- ZNF354A | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as COSV100234340; called by muse, mutect2, varscan2
- ZNF423 | c.1400A>G p.H467R (on ENST00000563137 / NM_001379286.1; = p.H459R on NM_015069.4) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99280147; called by muse, mutect2, varscan2
- ZNF433 | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100794946; called by muse, mutect2, varscan2
- ZNF490 | c.1289C>G p.S430C | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.592); catalogued as COSV100267209; called by muse, mutect2
- ZNF490 | c.982C>G p.H328D | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100267211; called by muse, mutect2
- ZNF536 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV62817522; called by muse, mutect2, varscan2
- ZNF536 | c.2282G>T p.R761L | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1258298418, COSV100834760, COSV62822939; called by muse, mutect2, varscan2
- ZNF536 | c.3406G>C p.D1136H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as COSV100834761; called by muse, mutect2, varscan2
- ZNF596 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1350634009, COSV100261525; called by muse, mutect2, varscan2
- ZNF600 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs776175562, COSV100592885, COSV100592917; called by muse, mutect2
- ZNF606 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV100071665; called by muse, mutect2, varscan2
- ZNF613 | c.16-1G>A p.X6_splice | Splice Site (SNP) | VAF 31/158 reads (20%) | catalogued as COSV99522842; called by muse, mutect2, varscan2
- ZNF625 | c.1034G>A p.S345N | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV100502859; called by muse, mutect2, varscan2
- ZNF675 | c.1562C>G p.S521* | Nonsense Mutation (SNP) | VAF 5/112 reads (4%) | catalogued as COSV100704925; called by muse, mutect2
- ZNF749 | c.1633C>T p.Q545* | Nonsense Mutation (SNP) | VAF 25/108 reads (23%) | catalogued as COSV100494215; called by muse, mutect2, varscan2
- ZNF835 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759310456, COSV73379501; called by muse, mutect2
- ZNF91 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs12976753, COSV56080852; called by muse, mutect2, varscan2
- ZRANB1 | c.1760C>G p.S587C | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs1480391772, COSV100456174; called by muse, mutect2
- ZXDB | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV100885794; called by muse, mutect2, varscan2
- AMER3 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ANAPC4 | c.2149_2150del p.M717Efs*28 | Frame Shift Del (DEL) | VAF 19/128 reads (15%) | called by mutect2, pindel, varscan2
- ANXA9 | c.927_928del p.R309Sfs*2 | Frame Shift Del (DEL) | VAF 42/210 reads (20%) | called by pindel, varscan2
- APCS | c.75del p.K26Rfs*14 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel, varscan2
- ATG9B | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2
- ATP6V0A2 | c.663del p.K221Nfs*6 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | called by mutect2, pindel, varscan2
- CXXC5 | c.340dup p.L114Pfs*7 | Frame Shift Ins (INS) | VAF 12/108 reads (11%) | called by mutect2, varscan2
- DARS2 | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.174); called by muse, mutect2
- LPA | c.998G>T p.C333F | Missense Mutation (SNP) | VAF 6/701 reads (1%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MIEN1 | c.284_309del p.R95Kfs*46 | Frame Shift Del (DEL) | VAF 16/162 reads (10%) | called by mutect2, pindel
- NBEA | c.4516del p.E1506Kfs*6 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- PCDH11Y | c.3586_3587del p.Q1196Dfs*67 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | called by pindel, varscan2
- PCNX2 | c.883dup p.I295Nfs*22 | Frame Shift Ins (INS) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- PLAC1 | c.281_287del p.Y94Lfs*15 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | called by mutect2, pindel
- PTPRJ | c.3269C>T p.S1090L | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.317); called by muse, mutect2
- SULF1 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TMEM184A | c.133dup p.A45Gfs*108 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- TTN | c.77644del p.T25882Hfs*2 (on ENST00000591111; = p.T18458Hfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 36/166 reads (22%) | called by mutect2, pindel, varscan2
- VARS2 | c.1113del p.Q372Sfs*20 | Frame Shift Del (DEL) | VAF 43/363 reads (12%) | called by mutect2, pindel, varscan2
- AC008397.2 | c.1452G>A p.Q484= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV99441268; called by muse, mutect2, varscan2
- ACTRT2 | c.738C>T p.D246= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs767066846, COSV101007511; called by muse, mutect2, varscan2
- ADAM11 | c.843C>G p.L281= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV52347062; called by muse, mutect2, varscan2
- ADGRV1 | c.12210C>A p.V4070= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV101315538, COSV67984133; called by muse, mutect2, varscan2
- AKAP12 | c.5205A>G p.Q1735= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99482540; called by muse, mutect2
- AKR1B10 | c.780C>T p.V260= | Silent (SNP) | VAF 40/194 reads (21%) | catalogued as rs555300572, COSV100610143; called by muse, mutect2, varscan2
- ALDH3B2 | c.249C>T p.A83= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs764515686, COSV100823982; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4392A>G p.K1464= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99782250; called by muse, mutect2
- AP1G1 | c.987G>A p.L329= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs771861609, COSV100250088; called by muse, mutect2, varscan2
- AP2S1 | c.129C>T p.D43= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs374514769, COSV54384152; called by muse, mutect2, varscan2
- ARID1A | c.3063G>A p.K1021= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100250494; called by muse, mutect2, varscan2
- ARSG | c.621C>G p.L207= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV101477873, COSV71593698; called by muse, mutect2, varscan2
- ASPM | c.9747C>G p.L3249= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99659645; called by muse, mutect2, varscan2
- ATG2A | c.2910C>T p.V970= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV101033906; called by muse, mutect2, varscan2
- ATP2B2 | c.1647C>T p.A549= (on ENST00000352432; = p.A515= on NM_001683.5) | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs1448623319, COSV100659714; called by muse, varscan2
- ATP2B4 | c.696G>C p.L232= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100397140; called by muse, mutect2
- ATP8B2 | c.2271C>T p.S757= (on ENST00000672630; = p.S724= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV100527682; called by muse, mutect2, varscan2
- AURKC | c.114C>T p.L38= (on ENST00000302804 / NM_001015878.2; = p.L4= on NM_003160.3) | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100248740; called by muse, mutect2, varscan2
- AZGP1 | c.153C>G p.G51= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV99447697; called by muse, mutect2, varscan2
- B3GALT4 | c.909C>T p.L303= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as rs930204927, COSV101005564; called by muse, mutect2, varscan2
- BBOX1 | c.180G>C p.V60= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV54189761, COSV99589435, COSV99589467; called by muse, mutect2, varscan2
- BEST2 | c.702C>T p.L234= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as rs1400190362, COSV99244249; called by muse, mutect2
- BRWD3 | c.4326G>A p.K1442= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV100955699; called by muse, mutect2, varscan2
- C10orf90 | c.621G>A p.L207= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs374201285; called by muse, mutect2, varscan2
- C9orf131 | c.600C>A p.P200= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV100397951; called by muse, mutect2
- CALR | c.441C>T p.I147= | Silent (SNP) | VAF 4/61 reads (7%) | catalogued as COSV100330460; called by muse, mutect2
- CCDC180 | c.888C>T p.S296= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100826586; called by muse, mutect2, varscan2
- CCS | c.51G>C p.A17= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100039773; called by muse, mutect2, varscan2
- CDC42BPB | c.1992C>G p.L664= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100775243; called by muse, mutect2
- CEP20 | c.480T>C p.S160= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV99739692; called by muse, mutect2, varscan2
- CGNL1 | c.1572G>A p.V524= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99847580; called by muse, mutect2, varscan2
- CNBD1 | c.753A>G p.L251= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV101575274; called by muse, mutect2
- CNKSR1 | c.816G>A p.R272= (on ENST00000374253 / NM_001297647.2; = p.R265= on NM_006314.3) | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as rs1451285096, COSV100836685; called by muse, mutect2
- COL18A1 | c.4398C>T p.L1466= (on ENST00000359759 / NM_130444.3; = p.L1231= on NM_030582.4) | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs764656377, COSV100645026; called by muse, mutect2, varscan2
- CPXM1 | c.468C>G p.G156= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV101013686, COSV66045120; called by muse, mutect2, varscan2
- CUBN | c.1461C>T p.Y487= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100912138; called by muse, mutect2, varscan2
- CYP2E1 | c.207G>A p.T69= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs77188198; called by muse, mutect2, varscan2
- CYP4A22 | c.672G>A p.L224= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99594639; called by muse, mutect2
- CYP4F12 | c.894C>T p.F298= | Silent (SNP) | VAF 7/159 reads (4%) | catalogued as COSV104410439, COSV61173187; called by muse, mutect2
- CYTH3 | c.594C>T p.I198= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100641294; called by muse, mutect2, varscan2
- DAGLA | c.1386A>G p.K462= | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as COSV99944045; called by muse, mutect2, varscan2
- DCC | c.1423C>A p.R475= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs546252561, COSV59105253; called by muse, mutect2, varscan2
- DCHS1 | c.4333C>T p.L1445= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1265846231, COSV100201571; called by muse, mutect2, varscan2
- DCLK3 | c.936T>A p.T312= | Silent (SNP) | VAF 35/211 reads (17%) | catalogued as COSV101373886; called by muse, mutect2, varscan2
- DEFB127 | c.246A>G p.Q82= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs752080511, COSV101213784; called by muse, mutect2, varscan2
- DFFA | c.64C>T p.L22= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV100749997; called by muse, mutect2
- DGKD | c.1833G>A p.L611= (on ENST00000264057 / NM_152879.3; = p.L567= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV51035541; called by muse, mutect2, varscan2
- DMRT1 | c.915C>A p.P305= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs1457061085, COSV101206619; called by muse, mutect2, varscan2
- DMWD | c.969G>A p.K323= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV99352780; called by muse, mutect2, varscan2
- DNAJC10 | c.2361G>A p.K787= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99898928; called by muse, mutect2, varscan2
- DNAJC3 | c.261A>T p.S87= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV100953290; called by muse, mutect2, varscan2
- DUSP28 | c.276G>T p.A92= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1207209287, COSV99801418; called by muse, mutect2
- DYNC2I1 | c.54C>G p.L18= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV101237836; called by muse, mutect2, varscan2
- EIF3M | c.546A>G p.S182= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100024873; called by muse, mutect2, varscan2
- ENO2 | c.1026C>G p.L342= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99980187; called by muse, mutect2, varscan2
- ETV5 | c.336T>C p.Y112= | Silent (SNP) | VAF 38/348 reads (11%) | catalogued as rs76963399, COSV100112081; called by muse, mutect2, varscan2
- FAM9C | c.357G>A p.L119= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100452757; called by muse, mutect2, varscan2
- FASN | c.1974G>A p.V658= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100147332, COSV100147414; called by muse, mutect2, varscan2
- FAT2 | c.12759C>T p.P4253= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV55827998; called by muse, mutect2, varscan2
- FAT3 | c.9765C>G p.V3255= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99962572; called by muse, mutect2, varscan2
- FBL | c.258G>T p.V86= | Silent (SNP) | VAF 62/309 reads (20%) | catalogued as COSV99695176; called by muse, mutect2, varscan2
- FLT4 | c.3375C>T p.C1125= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV56120330; called by muse, mutect2, varscan2
- FMNL2 | c.2073G>C p.V691= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99979012; called by muse, mutect2, varscan2
- GABRQ | c.33G>A p.V11= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100941107; called by muse, mutect2, varscan2
- GCM2 | c.876T>C p.Y292= | Silent (SNP) | VAF 22/273 reads (8%) | catalogued as COSV101069442; called by muse, mutect2
- GIPC2 | c.210C>A p.I70= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99503793; called by muse, mutect2
- GPR173 | c.1017C>G p.V339= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100212066; called by muse, mutect2, varscan2
- GPR35 | c.879C>T p.P293= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as COSV100166345; called by muse, mutect2
- GTF3C4 | c.1350G>A p.L450= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100935912; called by muse, mutect2, varscan2
- H2BC10 | c.153C>G p.P51= | Silent (SNP) | VAF 73/423 reads (17%) | catalogued as COSV100010024, COSV59952788, COSV59953600; called by muse, mutect2, varscan2
- HEATR3 | c.1266C>T p.L422= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs766971657, COSV99589782; called by muse, mutect2, varscan2
- HJV | c.258T>C p.Y86= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs782705202, COSV100382207; called by muse, mutect2, varscan2
- HLX | c.588G>C p.L196= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100854465; called by muse, mutect2, varscan2
- HOXD12 | c.807C>A p.L269= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV101184156; called by muse, mutect2, varscan2
- HPR | c.442C>T p.L148= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs1343561263, COSV99930814; called by muse, mutect2, varscan2
- IFFO1 | c.711G>A p.E237= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV100350839; called by muse, mutect2, varscan2
- IGSF22 | c.2457C>G p.S819= (on ENST00000319338; = p.S920= on NM_173588.4) | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99773539; called by muse, mutect2
- IL12B | c.525C>G p.L175= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99180327; called by muse, mutect2, varscan2
- IQSEC1 | c.1512C>T p.T504= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as COSV99831394; called by muse, mutect2, varscan2
- KCNA4 | c.1857G>A p.K619= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100068604; called by muse, mutect2, varscan2
- KCNJ4 | c.1038C>T p.P346= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100341029; called by muse, mutect2, varscan2
- KDM5A | c.804T>C p.V268= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV101238626; called by muse, mutect2, varscan2
- KIF4A | c.1218G>C p.L406= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs755057788, COSV100979406; called by muse, mutect2, varscan2
- KIF5B | c.2643G>T p.L881= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV100191475; called by muse, mutect2, varscan2
- KIFC1 | c.1734C>T p.L578= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs774299603, COSV65729299; called by muse, mutect2, varscan2
- KLHL8 | c.939G>A p.R313= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99911252; called by muse, mutect2, varscan2
- LAMA1 | c.6465C>G p.L2155= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV101055224, COSV67544097; called by muse, mutect2
- LATS1 | c.9G>A p.R3= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV99485382; called by muse, mutect2, varscan2
- LRFN2 | c.921A>C p.T307= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV100599153; called by muse, mutect2
- LRPPRC | c.2424G>A p.L808= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99579985; called by muse, mutect2, varscan2
- MAOA | c.1047C>T p.I349= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100108497, COSV100108638; called by muse, mutect2, varscan2
- MEPCE | c.1737C>T p.L579= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV99439812; called by muse, mutect2, varscan2
- METTL9 | c.414T>C p.L138= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as rs780669610, COSV100820512; called by muse, mutect2, varscan2
- MMP2 | c.1455C>T p.I485= | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as COSV99527464; called by muse, mutect2, varscan2
- MUC16 | c.23043G>A p.V7681= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV67446907; called by muse, mutect2, varscan2
- MYH15 | c.5451G>T p.L1817= | Silent (SNP) | VAF 33/214 reads (15%) | catalogued as COSV56305267, COSV56315465, COSV99842391; called by muse, mutect2, varscan2
- NANOS2 | c.195C>T p.F65= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100379463; called by muse, mutect2, varscan2
- NDUFA9 | c.135A>G p.K45= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs748095158, COSV99865317; called by muse, mutect2, varscan2
- NIBAN3 | c.447G>A p.L149= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV99961846; called by muse, mutect2, varscan2
- NMUR1 | c.807C>T p.A269= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100531820; called by muse, mutect2, varscan2
- NOXRED1 | c.192C>G p.L64= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100032878; called by muse, mutect2, varscan2
- NRAP | c.3993C>T p.I1331= (on ENST00000359988 / NM_001322945.2; = p.I1296= on NM_006175.4) | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100748298; called by muse, mutect2, varscan2
- NTM | c.876C>T p.N292= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs779852784, COSV66181610, COSV66196828; called by muse, mutect2, varscan2
- NUP188 | c.669A>G p.A223= | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as COSV101001214; called by muse, mutect2
- ODF2L | c.1032G>A p.L344= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs1558032659, COSV99643866; called by muse, mutect2, varscan2
- OR2T2 | c.312C>G p.L104= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as rs751406085, COSV61617857; called by muse, mutect2
- OTUD6A | c.666G>A p.L222= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100610937, COSV57973036; called by muse, mutect2, varscan2
- PCARE | c.2769C>T p.D923= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1222505969, COSV100527342; called by muse, mutect2, varscan2
- PCDHB10 | c.426A>T p.I142= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV99503756; called by muse, mutect2, varscan2
- PCLO | c.9090T>A p.V3030= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100427950, COSV61667377; called by muse, mutect2, varscan2
- PCLO | c.5199A>G p.S1733= | Silent (SNP) | VAF 50/145 reads (34%) | catalogued as COSV100427955; called by muse, mutect2, varscan2
- PCSK5 | c.123C>G p.V41= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100949586; called by muse, varscan2
- PDE1C | c.2070G>T p.L690= | Silent (SNP) | VAF 19/220 reads (9%) | catalogued as COSV100371274; called by muse, mutect2
- PDZD3 | c.705C>T p.F235= (on ENST00000531114; = p.F169= on NM_024791.4) | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99423812; called by muse, mutect2
- PIK3C2A | c.3501G>A p.L1167= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV99790309; called by muse, mutect2, varscan2
- PITRM1 | c.1851C>G p.L617= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV99828343; called by muse, mutect2, varscan2
- PKD2 | c.2286C>T p.Y762= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs555242193, CM971201, COSV99416920; ClinVar: benign; called by muse, mutect2, varscan2
- PPIP5K1 | c.870G>A p.E290= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as COSV100613083; called by muse, mutect2
- PRAMEF15 | c.1176C>A p.I392= | Silent (SNP) | VAF 26/372 reads (7%) | called by muse, mutect2
- PREX2 | c.3498C>T p.F1166= | Silent (SNP) | VAF 22/169 reads (13%) | catalogued as COSV99905382; called by muse, mutect2, varscan2
- PRR23B | c.501G>T p.R167= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100271939; called by muse, mutect2, varscan2
- PSMD2 | c.1335T>C p.L445= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as rs149124368; called by muse, mutect2, varscan2
- PXDN | c.3348G>T p.P1116= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs774824301, COSV99412464; called by muse, mutect2, varscan2
- RAB36 | c.876G>A p.V292= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99572106; called by muse, mutect2, varscan2
- RABGEF1 | c.774G>A p.L258= (on ENST00000439720 / NM_001287061.2; = p.L245= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV53161406; called by muse, mutect2, varscan2
- RANBP10 | c.1716C>G p.L572= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100449144; called by muse, mutect2, varscan2
- RASGRF2 | c.2497C>A p.R833= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99428614; called by muse, mutect2, varscan2
- RBP3 | c.711C>T p.G237= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs782037930; called by muse, mutect2, varscan2
- REV3L | c.8868G>A p.G2956= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100724924, COSV62619664; called by muse, mutect2, varscan2
- SASH1 | c.1545C>T p.L515= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV100820943; called by muse, mutect2
- SEMA4A | c.199C>T p.L67= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV100740468; called by muse, mutect2, varscan2
- SEZ6L | c.1059C>G p.L353= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV99961464; called by muse, mutect2, varscan2
- SFMBT1 | c.1884T>G p.S628= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99965855; called by muse, mutect2, varscan2
- SHANK1 | c.3537G>A p.A1179= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1418400152, COSV99520323; called by muse, mutect2, varscan2
- SIN3A | c.2655C>T p.L885= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100845052; called by muse, mutect2, varscan2
- SLC26A7 | c.1065A>G p.S355= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs755839022, COSV99402658; called by muse, mutect2
- SLC6A14 | c.525G>A p.V175= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100903077; called by muse, mutect2
- SLCO5A1 | c.564C>T p.F188= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs200066398, COSV52667191; called by muse, mutect2, varscan2
- SMG5 | c.1362T>C p.S454= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV100700712; called by muse, mutect2, varscan2
- SMPDL3B | c.1308C>G p.P436= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100874559; called by muse, mutect2, varscan2
- SNAPC4 | c.933A>G p.A311= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV100046860; called by muse, mutect2, varscan2
- SPEG | c.2241C>T p.A747= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100403442; called by muse, mutect2, varscan2
- SPTBN2 | c.4074G>C p.L1358= | Silent (SNP) | VAF 31/187 reads (17%) | catalogued as COSV100018324, COSV59448250; called by muse, mutect2, varscan2
- SSC4D | c.816C>T p.G272= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99299819; called by muse, varscan2
- STT3A | c.1329G>A p.K443= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV101205121; called by muse, mutect2, varscan2
- SUOX | c.345G>C p.V115= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99906938; called by muse, mutect2, varscan2
- TBC1D1 | c.909C>T p.I303= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV54714028; called by muse, mutect2
- TLR6 | c.561G>A p.E187= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV101126243; called by muse, mutect2, varscan2
- TMC3 | c.684G>A p.L228= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100845848; called by muse, mutect2, varscan2
- TMEM132D | c.1344G>T p.V448= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV101396610; called by mutect2, varscan2
- TNF | c.210C>T p.I70= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as COSV101403142; called by muse, mutect2, varscan2
- TNFRSF21 | c.150C>G p.L50= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99729209; called by muse, mutect2, varscan2
- TNIP3 | c.258C>G p.L86= | Silent (SNP) | VAF 41/362 reads (11%) | catalogued as rs1178620828, COSV99284304; called by muse, mutect2, varscan2
- TOGARAM1 | c.909G>A p.L303= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs1342384631, COSV61887446; called by muse, mutect2, varscan2
- TPTE | c.384T>C p.S128= (on ENST00000618007 / NM_199261.4; = p.S110= on NM_199259.4) | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- TREML2 | c.870G>A p.K290= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV101530143; called by muse, mutect2, varscan2
- TRGV2 | c.336C>T p.Y112= | Silent (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- TRIM38 | c.1155C>A p.L385= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as COSV100837541, COSV100837545; called by muse, mutect2
- TSHZ2 | c.1209T>C p.G403= | Silent (SNP) | VAF 27/173 reads (16%) | catalogued as rs1340041917, COSV100295483; called by muse, mutect2, varscan2
- TTN | c.57174A>T p.P19058= (on ENST00000591111; = p.P11634= on NM_003319.4) | Silent (SNP) | VAF 28/199 reads (14%) | catalogued as COSV100596876; called by muse, mutect2, varscan2
- TTN | c.28530C>G p.L9510= (on ENST00000591111; = p.L8583= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100596878; called by muse, mutect2, varscan2
- TTN | c.4860T>C p.T1620= (on ENST00000591111; = p.T1574= on NM_003319.4) | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs890860894, COSV100596883; called by muse, mutect2, varscan2
- TUBGCP2 | c.1965C>G p.L655= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99427053, COSV99427258; called by muse, mutect2, varscan2
- VPS13B | c.9003A>G p.L3001= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as COSV100660957; called by muse, mutect2, varscan2
- WDR33 | c.3261C>T p.F1087= | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as rs769898099, COSV59256639; called by muse, mutect2, varscan2
- ZBTB11 | c.327C>G p.V109= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV100465210; called by muse, mutect2, varscan2
- ZC3H12D | c.114G>A p.Q38= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV101116806; called by muse, mutect2
- ZIC4 | c.924G>A p.S308= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV67174624; called by muse, mutect2
- ZMYM3 | c.3516G>A p.L1172= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100077499; called by muse, mutect2, varscan2
- ZNF268 | c.792T>C p.L264= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99934746; called by muse, mutect2
- ZNF516 | c.1116G>T p.G372= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101487218; called by muse, mutect2
- ZNF93 | c.453G>T p.G151= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ZP4 | c.51G>C p.V17= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100850597; called by muse, mutect2, varscan2
- ZXDC | c.1653G>A p.G551= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100306295, COSV100306321; called by muse, mutect2, varscan2
- AP000769.3 | n.28C>T | RNA (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- AP000769.3 | n.29C>T | RNA (SNP) | VAF 8/50 reads (16%) | catalogued as rs1296369560; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506342 C>T | 3'Flank (SNP) | VAF 6/30 reads (20%) | catalogued as rs1276070862; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+197A>G | Intron (SNP) | VAF 31/160 reads (19%) | catalogued as COSV99180686; called by muse, mutect2, varscan2
- CARS2 | c.1417-96G>C | Intron (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- CCDC140 | n.654G>C | RNA (SNP) | VAF 5/34 reads (15%) | catalogued as rs1212843843, COSV99734970; called by muse, mutect2
- CCDC144B | n.435G>A | RNA (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- HMGB1P1 | n.139G>A | RNA (SNP) | VAF 31/241 reads (13%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.*139G>A | 3'UTR (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99240930; called by muse, mutect2, varscan2
- MACF1 | c.15832-11986G>A | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792083 C>T | 3'Flank (SNP) | VAF 8/42 reads (19%) | catalogued as rs113961788; called by muse, mutect2, varscan2
- SARDH | c.1020+237G>C | Intron (SNP) | VAF 29/188 reads (15%) | catalogued as COSV100897877; called by muse, mutect2, varscan2
- SNORD116-21 | n.86G>C | RNA (SNP) | VAF 46/303 reads (15%) | called by muse, mutect2, varscan2
- TMEM105 | n.638C>A | RNA (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100129588; called by muse, mutect2, varscan2
- TTN | c.10303+2377A>G | Intron (SNP) | VAF 9/76 reads (12%) | catalogued as rs778116553, COSV100596881; called by muse, mutect2, varscan2
- VN1R10P | n.680G>A | RNA (SNP) | VAF 33/248 reads (13%) | called by muse, mutect2, varscan2
- WFDC2 | c.224-284C>T | Intron (SNP) | VAF 12/96 reads (13%) | catalogued as rs761688499, COSV99463642; called by muse, mutect2, varscan2
- ZNF658B | n.1820C>T | RNA (SNP) | VAF 10/44 reads (23%) | called by mutect2, varscan2
